Somatic mutation profile of tumor specimen 0cc794c3-5bf5-4621-b238-58a0f6 (aliquot 0cc794c3-5bf5-4621-b238-58a0f6_D6) from CPTAC case 04OV050, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIB.
Specimen 0cc794c3-5bf5-4621-b238-58a0f6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d000caa7-0055-4762-a9ca-f425608e5377.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 73f0ce85-40bf-4244-b233-d2e764 (Blood Derived Normal), aliquot 73f0ce85-40bf-4244-b233-d2e764_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f9a1dc8-7368-40c5-874d-24c1af1a95e1

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 3, 3'UTR 2, Intron 1, 5'UTR 1, Splice Region 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 88/170 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1043G>A p.W348* | Nonsense Mutation (SNP) | VAF 37/85 reads (44%) | catalogued as COSV70029989; called by muse, mutect2, varscan2
- ABCC6 | c.3293A>G p.Y1098C | Missense Mutation (SNP) | VAF 66/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261061440; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- ARAF | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1413219188, COSV51695145; called by muse, mutect2, varscan2
- ARHGAP23 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs777310873; called by muse, mutect2, varscan2
- ATP23 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.886); catalogued as rs200432568; called by muse, mutect2, varscan2
- CELF3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 30/369 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs754604007, COSV99066717; called by muse, mutect2
- FRMPD3 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as rs778005749; called by muse, mutect2, varscan2
- HERC2 | c.2288T>C p.I763T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV55351867; called by muse, mutect2, varscan2
- ITPR1 | c.6607C>T p.R2203* (on ENST00000354582; = p.R2148* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as rs1468316953, COSV100233057; called by muse, mutect2, varscan2
- KCNC2 | c.1473G>T p.R491S | Missense Mutation (SNP) | VAF 90/319 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100129271; called by muse, mutect2, varscan2
- KDM5A | c.3997C>T p.R1333* | Nonsense Mutation (SNP) | VAF 31/266 reads (12%) | catalogued as COSV66996472; called by muse, mutect2, varscan2
- KIDINS220 | c.4708A>G p.K1570E | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779569943; called by muse, mutect2, varscan2
- OR5M8 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 80/224 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1398677774, COSV59116691; called by muse, mutect2, varscan2
- QRICH2 | c.2912C>T p.S971L | Missense Mutation (SNP) | VAF 52/471 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760784225; called by muse, mutect2, varscan2
- SLC5A2 | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 200/567 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749157030; called by muse, mutect2, varscan2
- TAB1 | c.1374C>G p.D458E | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as rs757969422; called by muse, mutect2
- TCHHL1 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as COSV64284708; called by muse, mutect2, varscan2
- TRIML1 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV60196617; called by muse, mutect2, varscan2
- WDR47 | c.1954G>T p.V652L (on ENST00000369962 / NM_001142551.2; = p.V653L on NM_014969.5) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs971524749; called by muse, mutect2
- WFDC10B | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as rs200120473; called by muse, mutect2, varscan2
- ARHGAP35 | c.1348_1349delinsC p.K450Rfs*11 | Frame Shift Del (DEL) | VAF 33/111 reads (30%) | called by pindel, varscan2*
- CCDC8 | c.442del p.D148Mfs*59 | Frame Shift Del (DEL) | VAF 84/256 reads (33%) | called by mutect2, varscan2
- CEACAM21 | c.715C>G p.L239V (on ENST00000401445 / NM_001098506.4; = p.L238V on NM_033543.6) | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP70 | c.2582T>G p.F861C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CUBN | c.7820del p.N2607Ifs*16 | Frame Shift Del (DEL) | VAF 79/247 reads (32%) | called by mutect2, pindel, varscan2
- E2F1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 138/370 reads (37%) | called by muse, mutect2, varscan2
- ERRFI1 | c.909dup p.E304Rfs*8 | Frame Shift Ins (INS) | VAF 107/322 reads (33%) | called by mutect2, pindel, varscan2
- FAM222B | c.426C>G p.S142R | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FCGBP | c.391A>T p.T131S | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.793); called by muse, mutect2
- GPC5 | c.1279del p.S427Vfs*28 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- GPR143 | c.638T>C p.F213S | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITPR1 | c.5956-7A>G | Splice Region (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- MYO1E | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 117/321 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NDST2 | c.788_814del p.P263_L271del | In Frame Del (DEL) | VAF 24/224 reads (11%) | called by mutect2, pindel
- NUP153 | c.2623G>T p.E875* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- PEG3 | c.3841C>G p.L1281V | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXNB2 | c.2341T>A p.W781R | Missense Mutation (SNP) | VAF 89/152 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLA1 | c.1645A>G p.N549D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- STRIP1 | c.2096dup p.R700Afs*57 | Frame Shift Ins (INS) | VAF 89/321 reads (28%) | called by mutect2, pindel, varscan2
- TBC1D32 | c.2549A>G p.Q850R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- VCAN | c.2715_2716insTT p.V906Lfs*24 | Frame Shift Ins (INS) | VAF 78/220 reads (35%) | called by mutect2, varscan2
- ABCB6 | c.267C>G p.A89= | Silent (SNP) | VAF 87/211 reads (41%) | called by muse, mutect2, varscan2
- BACH2 | c.1011G>A p.S337= | Silent (SNP) | VAF 42/119 reads (35%) | catalogued as rs780976281; called by muse, mutect2, varscan2
- CCDC85C | c.1158C>T p.R386= | Silent (SNP) | VAF 58/138 reads (42%) | catalogued as rs572012873; called by muse, mutect2, varscan2
- CCR10 | c.888C>T p.S296= | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as rs758868599, COSV99226739; called by muse, mutect2, varscan2
- CFAP46 | c.2566C>A p.R856= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs771061338; called by muse, mutect2, varscan2
- CRB2 | c.2127G>A p.V709= | Silent (SNP) | VAF 92/227 reads (41%) | catalogued as rs778851199; called by muse, mutect2, varscan2
- DCSTAMP | c.150C>G p.A50= | Silent (SNP) | VAF 118/326 reads (36%) | catalogued as COSV99886108; called by muse, mutect2, varscan2
- GRAMD1B | c.1812G>A p.T604= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as rs149202511, COSV59211665; called by muse, mutect2, varscan2
- MGAM | c.3711G>A p.V1237= | Silent (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- MON1A | c.450T>C p.H150= | Silent (SNP) | VAF 38/103 reads (37%) | catalogued as rs752747491; called by muse, mutect2, varscan2
- OR2T11 | c.243C>T p.D81= | Silent (SNP) | VAF 131/195 reads (67%) | catalogued as COSV100424709; called by muse, mutect2, varscan2
- SLC44A4 | c.1977C>T p.F659= | Silent (SNP) | VAF 17/143 reads (12%) | catalogued as rs1169610778; called by muse, mutect2, varscan2
- ZNF143 | c.1875G>T p.A625= | Silent (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- ADM2 | c.*181C>T | 3'UTR (SNP) | VAF 91/189 reads (48%) | catalogued as rs1371051971; called by muse, mutect2, varscan2
- MECR | c.892-10G>C | Intron (SNP) | VAF 99/274 reads (36%) | called by muse, mutect2, varscan2
- TTC39A | c.-36_-19del | 5'UTR (DEL) | VAF 52/74 reads (70%) | called by mutect2, varscan2
- UBE2DNL | n.406T>A | RNA (SNP) | VAF 186/560 reads (33%) | called by muse, mutect2, varscan2
- ZNF99 | c.*2834A>T | 3'UTR (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
